Surgical pathology report (de-identified scan), TCGA case TCGA-FG-5964, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-5964-01A (Primary Tumor).

FINAL DIAGNOSIS

A. LEFT PARIETAL LOBE OF BRAIN, LESION, BIOPSIES AND REMOVAL:
-- OLIGODENDROGLIOMA (WHO GRADE II).

Note: An addendum will be issued pending analyses for deletions in chromosomes 1p and 19q.

Intraoperative Consultation:

A. Microscopic Diagnosis: High grade glioma.

Addendum/Procedures:

Addendum

Date Ordered: [REDACTED]
Date Complete: [REDACTED]
Date Reported: [REDACTED]

Status: Signed Out

Addendum Diagnosis

Fluorescence in situ hybridization, performed at the [REDACTED] demonstrates loss of both chromosomes 1p and 19q. a copy of their report is on file in the Department of Pathology.

Electronically Signed Out By

Clinical History:

l parietal lesion

Specimens Submitted As:

A:L PAREITAL PARYNCYMAL LESION
B:LEFT PARIETAL PARENCYMAL LESION
C:LEFT BRAIN TUMOR

Gross Description:

A. Received fresh for intraoperative consultation labeled with the patient's name, hospital number and "left parietal parenchymal lesion" consists of one irregular tan-red fragment of soft tissue, 1.1 x 0.9 x 0.2 cm. A touch imprint is performed. A portion of the specimen is submitted for frozen section analysis. The remainder of the specimen is entirely submitted for permanent section in 2 cassettes.

B: Received in formalin, labeled with the patient's name, number, and "left parietal parenchymal lesion, probable tumor or infarct", are multiple light tan to focally red-brown irregular soft tissue fragments measuring 1.5 x 1.0 x 0.5 cm in aggregate. Submitted in toto in one cassette.

C: Received in formalin labeled with patient's name and number, are multiple light tan to pink- tan irregular soft tissue fragment measuring 1.3 x 0.8 x 0.6 cm in aggregate. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file 377b28b0-54bf-47f1-8dd5-f52beb8b896d (TCGA-FG-5964.BCAFF494-0EF3-42B0-8D93-54D6A8598397.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).